Somatic mutation profile of tumor specimen BLGSP-71-19-00114-02A (aliquot BLGSP-71-19-00114-02A-01D-A634-33) from CGCI case BLGSP-71-19-00114, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 3.0 years (1,114 days).
Specimen BLGSP-71-19-00114-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Biospecimen anatomic site: Small Bowel; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6428886f-5006-4422-abfa-eae6e6b8f80e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00114-16A (Mononuclear Cells from Bone Marrow Normal), aliquot BLGSP-71-19-00114-16A-01D-A634-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64ae4591-b675-4be2-85bc-76f6b8f89a1f

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | hotspot (GDC flag); catalogued as COSV57828583; called by muse, mutect2, varscan2
- RHOA | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 29/491 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1057519953, COSV69041526, COSV69042045; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.613T>G p.Y205D | Missense Mutation (SNP) | VAF 86/222 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CARD11 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV67802201; called by muse, mutect2, varscan2
- CARD11 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62717294; called by muse, mutect2, varscan2
- GNA13 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 97/339 reads (29%) | catalogued as COSV71474564; called by muse, mutect2, varscan2
- MYC | c.18C>T p.S6= (on ENST00000377970; = p.S21= on NM_002467.6) | Silent (SNP) | VAF 61/809 reads (8%) | catalogued as rs772792914, COSV52367888, COSV52373284; called by muse, mutect2
- MYC | c.300G>A p.E100= (on ENST00000377970; = p.E115= on NM_002467.6) | Silent (SNP) | VAF 68/189 reads (36%) | called by muse, varscan2
